Somatic mutation profile of tumor specimen 0DWWN3 from CCDI case PBCPBB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, metastatic; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.8 years (1,015 days).
Specimen 0DWWN3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59187c46-9a40-4813-98f5-889e44c7f76c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWWMC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a29a9fa-75b4-4aac-a9e1-7a807db3face

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD18A | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 206/456 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs546726195; called by muse, mutect2, varscan2
- LAMA5 | c.8741A>G p.N2914S | Missense Mutation (SNP) | VAF 175/386 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as rs1331450355; called by muse, mutect2, varscan2
- IGSF3 | c.3551C>G p.P1184R (on ENST00000369486 / NM_001007237.3; = p.P1204R on NM_001542.4) | Missense Mutation (SNP) | VAF 173/368 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB9 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 196/448 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR42 | c.684G>A p.A228= | Silent (SNP) | VAF 302/566 reads (53%) | catalogued as rs765579792; called by muse, mutect2, varscan2
- WDFY3 | c.882C>T p.S294= | Silent (SNP) | VAF 17/406 reads (4%) | catalogued as rs1472548658; called by muse, mutect2
